Somatic mutation profile of tumor specimen TCGA-L6-A4EU-01A (aliquot TCGA-L6-A4EU-01A-11D-A257-08) from TCGA case TCGA-L6-A4EU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 58.0 years (21,192 days).
Specimen TCGA-L6-A4EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bd89311-469f-4a3c-a6b7-1bd4d026b24c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L6-A4EU-10A (Blood Derived Normal), aliquot TCGA-L6-A4EU-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fee24144-8588-4fb0-9ff5-939a5c3478e3

The open-access MAF lists 51 somatic variants for this specimen: 32 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 15, Nonsense Mutation 3, Splice Site 2, 3'Flank 2, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS9 | c.5293-1G>C p.X1765_splice | Splice Site (SNP) | VAF 6/137 reads (4%) | catalogued as COSV99898763; called by muse, mutect2
- ALPK1 | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV99453090; called by muse, mutect2, varscan2
- CACNA1E | c.6440C>G p.S2147C (on ENST00000367573 / NM_001205293.3; = p.S2104C on NM_000721.4) | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs777197271, COSV62385187; called by muse, mutect2
- CARD6 | c.2737C>T p.Q913* | Nonsense Mutation (SNP) | VAF 11/202 reads (5%) | catalogued as COSV54564795; called by muse, mutect2
- CARD6 | c.2864C>G p.S955C | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as rs751293523, COSV54564809; called by muse, mutect2
- CBX5 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV52935920, COSV52938937; called by muse, mutect2, varscan2
- CEMIP2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs762039271, COSV65485945; called by muse, mutect2, varscan2
- CLEC3A | c.387G>C p.R129S (on ENST00000651443; = p.R120S on NM_005752.6) | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55220137; called by muse, mutect2, varscan2
- COX20 | c.356G>C p.*119Sext*29 | Nonstop Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100834632; called by muse, mutect2
- DDX58 | c.2576G>A p.R859K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754726367, COSV59377701; called by muse, mutect2, varscan2
- DPYSL5 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.434); catalogued as rs1558357075, COSV56509673; called by muse, mutect2, varscan2
- DST | c.3494C>T p.S1165F (on ENST00000361203 / NM_001374722.1; = p.S839F on NM_001723.6) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV55002250; called by muse, mutect2
- FAM53B | c.1064T>G p.V355G | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV61559982; called by muse, mutect2, varscan2
- KEL | c.1071G>C p.Q357H | Missense Mutation (SNP) | VAF 23/389 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62333814; called by muse, mutect2
- KLHDC8B | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV60411432; called by muse, mutect2, varscan2
- LRPPRC | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV53235232; called by muse, mutect2, varscan2
- MACF1 | c.7277C>T p.S2426L | Missense Mutation (SNP) | VAF 5/94 reads (5%) | catalogued as COSV57110695; called by muse, mutect2
- MST1R | c.2650-1G>A p.X884_splice | Splice Site (SNP) | VAF 57/191 reads (30%) | catalogued as COSV56565850; called by muse, mutect2, varscan2
- MTERF2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV53527112; called by muse, mutect2, varscan2
- OPN4 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as rs1402237279, COSV54115184; called by muse, mutect2
- PELO | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV50877147; called by muse, mutect2, varscan2
- RALGAPB | c.1636A>T p.I546F | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.395); catalogued as COSV53435509; called by muse, mutect2, varscan2
- THOC5 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV63797795; called by muse, mutect2
- TMEM38A | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51818332, COSV51818533; called by muse, mutect2
- TRIM51 | c.903C>G p.F301L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV55264624; called by muse, mutect2
- UBP1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV52144862; called by muse, mutect2
- ZNF721 | c.1419_1421del p.S475del (on ENST00000338977; = p.S487del on NM_133474.4) | In Frame Del (DEL) | VAF 19/47 reads (40%) | catalogued as rs782142616; called by mutect2, pindel, varscan2
- C9orf152 | c.286_289del p.S96Rfs*69 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | called by mutect2, pindel, varscan2
- DDX43 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA1 | c.605_611dup p.E205Rfs*14 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, varscan2
- SLC10A5 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- BEND7 | c.171C>G p.L57= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV61987758; called by muse, mutect2
- COL4A5 | c.1263T>G p.P421= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV60357696; called by muse, mutect2, varscan2
- CPA1 | c.1245G>C p.L415= | Silent (SNP) | VAF 14/300 reads (5%) | catalogued as COSV50568343, COSV50576480; called by muse, mutect2
- FER1L6 | c.3063C>T p.C1021= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs369624500, COSV67548672; called by muse, mutect2, varscan2
- FRMD4A | c.1501C>T p.L501= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV52717274, COSV52736793; called by muse, mutect2, varscan2
- GPR89B | c.129C>T p.I43= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100032375; called by muse, mutect2, varscan2
- HMOX2 | c.396G>A p.Q132= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV54859663; called by muse, mutect2
- LOX | c.426G>A p.A142= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV50237010; called by muse, mutect2, varscan2
- NUDT10 | c.345G>A p.R115= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100726780; called by muse, mutect2
- SERTAD3 | c.18G>A p.K6= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV59324655; called by muse, mutect2, varscan2
- SPATA31A1 | c.2016G>A p.G672= | Silent (SNP) | VAF 46/300 reads (15%) | catalogued as rs1411064406; called by mutect2, varscan2
- UBE2A | c.54G>A p.E18= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV60636064, COSV60637323; called by muse, mutect2, varscan2
- VPS35L | c.2865C>T p.L955= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV51978577; called by muse, mutect2, varscan2
- ZFC3H1 | c.360T>G p.P120= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as COSV57348138; called by muse, mutect2, varscan2
- ZFHX3 | c.10755T>G p.S3585= | Silent (SNP) | VAF 51/133 reads (38%) | catalogued as COSV51711669; called by muse, mutect2, varscan2
- AP2A2 | c.*440C>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs1485459052, COSV100172502; called by muse, mutect2
- EPSTI1 | chr13:42888358 G>A | 3'Flank (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100552707, COSV58044407; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158059 C>T | 3'Flank (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
